Somatic mutation profile of tumor specimen MP2PRT-PAUFZF-TMP1-A (aliquot MP2PRT-PAUFZF-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUFZF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (988 days).
Specimen MP2PRT-PAUFZF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bdd4af3-4884-4031-b181-bcd9ec09c2f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUFZF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUFZF-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33292194-aac1-4798-b528-20bccba18886

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABRA3 | c.138C>T p.G46= | Splice Region (SNP) | VAF 71/94 reads (76%) | catalogued as COSV64797696; called by muse, mutect2, varscan2
- GNB1 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 98/362 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101060727; called by muse, mutect2, varscan2
- FBXO22 | c.975A>G p.A325= | Silent (SNP) | VAF 151/378 reads (40%) | called by muse, mutect2, varscan2
- ZNF516 | c.2796G>A p.T932= | Silent (SNP) | VAF 139/456 reads (30%) | catalogued as rs368519568; called by muse, mutect2, varscan2
